Somatic mutation profile of tumor specimen TCGA-C5-A1M6-01A (aliquot TCGA-C5-A1M6-01A-11D-A13W-08) from TCGA case TCGA-C5-A1M6, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.0 years (20,090 days).
Specimen TCGA-C5-A1M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81292c56-85f4-4a93-848e-1acc5354c787.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1M6-10A (Blood Derived Normal), aliquot TCGA-C5-A1M6-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a2d6ed4-8b63-4b7f-bc05-f42ee5c93c95

The open-access MAF lists 157 somatic variants for this specimen: 113 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 40, Nonsense Mutation 13, Intron 2, Frame Shift Ins 2, Frame Shift Del 1, RNA 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP2 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131690792, COSV52231308; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.4093C>T p.Q1365* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV53318685, COSV53326417; called by muse, mutect2, varscan2
- ACAP2 | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100462289, COSV58754307; called by muse, mutect2, varscan2
- AKIRIN2 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs930188008, COSV57637127; called by muse, mutect2, varscan2
- ANKRD26 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373943537; called by muse, mutect2, varscan2
- AREL1 | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.931); catalogued as rs757606025, COSV62666967, COSV62667431; called by muse, mutect2, varscan2
- ARFGEF3 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs138456342; called by muse, mutect2, varscan2
- ATP10D | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1454371202, COSV56710983; called by muse, mutect2, varscan2
- BRINP2 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV64176813, COSV64179229; called by muse, mutect2, varscan2
- C2CD3 | c.4621G>A p.G1541R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.99); PolyPhen benign (0.076); catalogued as rs111402521, COSV58097394; called by muse, mutect2, varscan2
- CASP10 | c.1100C>T p.S367L (on ENST00000272879 / NM_032974.5; = p.S324L on NM_001230.5) | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs774726645, COSV53779277; called by muse, mutect2, varscan2
- CDKN2AIP | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368122042; called by muse, mutect2, varscan2
- CEBPZ | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99135399; called by muse, mutect2
- CEP128 | c.2920G>C p.E974Q | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55385370, COSV55392204; called by muse, mutect2, varscan2
- CHST11 | c.528G>C p.L176F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57991879; called by mutect2, varscan2
- CPN1 | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64942634; called by muse, mutect2, varscan2
- CRYBG3 | c.6127G>C p.E2043Q | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51714555; called by muse, mutect2, varscan2
- CTAGE1 | c.781T>A p.L261M | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV101194425; called by muse, mutect2
- CTSH | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.714); catalogued as COSV54985875; called by muse, mutect2, varscan2
- CUL5 | c.878T>G p.L293* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV67609745; called by muse, mutect2, varscan2
- DYNC1H1 | c.4033C>T p.Q1345* | Nonsense Mutation (SNP) | VAF 78/155 reads (50%) | catalogued as COSV64140204; called by muse, mutect2, varscan2
- EDEM1 | c.1527C>G p.F509L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56581942; called by muse, mutect2, varscan2
- EMC9 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1431528577, COSV52825291; called by muse, mutect2, varscan2
- EMD | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as COSV63962360; called by muse, mutect2, varscan2
- ENOX2 | c.997G>C p.E333Q (on ENST00000338144 / NM_001382520.1; = p.E304Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV57655958; called by muse, mutect2, varscan2
- ENPP2 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs775542252, COSV50027592; called by muse, mutect2, varscan2
- EXOSC9 | c.332G>C p.R111T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV54667335; called by muse, mutect2, varscan2
- F5 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63126385; called by muse, mutect2, varscan2
- FGF9 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.581); catalogued as COSV66645312; called by muse, mutect2, varscan2
- FOXD4 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58701687; called by muse, mutect2, varscan2
- FOXJ2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50820510; called by muse, mutect2, varscan2
- FRMPD2 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV59718246, COSV59721496; called by muse, mutect2, varscan2
- FYCO1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56118267; called by muse, mutect2, varscan2
- GCG | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV64961900, COSV64962228; called by muse, mutect2, varscan2
- GNAT1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV50033103; called by muse, mutect2, varscan2
- GOLGB1 | c.4852C>G p.L1618V | Missense Mutation (SNP) | VAF 111/363 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510738, COSV61468879, COSV61470630; called by muse, mutect2, varscan2
- GRN | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 57/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751651838, COSV50008229; called by muse, mutect2, varscan2
- H3-3A | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100831247, COSV64733188; called by muse, mutect2, varscan2
- IQSEC1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.915); catalogued as COSV56227073; called by muse, mutect2, varscan2
- IRF8 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99236019; called by muse, mutect2
- ITGA8 | c.1726A>T p.K576* | Nonsense Mutation (SNP) | VAF 112/291 reads (38%) | catalogued as COSV65233214; called by muse, mutect2, varscan2
- IZUMO1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV55803874; called by muse, mutect2, varscan2
- KPNA6 | c.60T>A p.N20K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65361472; called by muse, varscan2
- KPNA6 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV65361478; called by muse, varscan2
- KRT6B | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52885425, COSV99360546; called by muse, mutect2, varscan2
- LAMP1 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV58151341; called by muse, mutect2, varscan2
- LCT | c.5599G>A p.E1867K | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99738623; called by muse, mutect2
- LETMD1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 138/191 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV50398868; called by muse, mutect2, varscan2
- LRPPRC | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 51/304 reads (17%) | catalogued as COSV53241288; called by muse, mutect2, varscan2
- LYPD3 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754129433, COSV54989350; called by muse, mutect2, varscan2
- MARCHF6 | c.2263C>G p.P755A | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV56879542, COSV56884743; called by muse, mutect2, varscan2
- MARK1 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV65066110, COSV65069936; called by muse, mutect2, varscan2
- MAST4 | c.2030C>T p.T677M (on ENST00000403625 / NM_001164664.2; = p.T488M on NM_015183.3) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375581688; called by muse, mutect2, varscan2
- MTMR9 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs375789918; called by muse, mutect2, varscan2
- MYH1 | c.4423C>G p.Q1475E | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV56849391; called by muse, mutect2, varscan2
- NFE2L3 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV50234254, COSV50238816; called by muse, mutect2, varscan2
- NLRP3 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200258061, COSV60220327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP9 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 113/203 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376663019, COSV60466137; called by muse, mutect2, varscan2
- NUDT1 | c.190G>C p.E64Q (on ENST00000397048 / NM_198952.1; = p.E41Q on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.255); catalogued as COSV54248821; called by muse, mutect2, varscan2
- NUTF2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54646934; called by muse, varscan2
- OR1N1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1359832076, COSV59196246; called by muse, mutect2, varscan2
- OXNAD1 | c.927G>T p.E309D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53267947; called by muse, mutect2, varscan2
- PBRM1 | c.1724T>A p.I575N | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56292859; called by muse, mutect2, varscan2
- PCDHB2 | c.2113T>C p.F705L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1554271663, COSV50605189; called by muse, mutect2, varscan2
- PCYT1B | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV63265901; called by muse, mutect2, varscan2
- PLA1A | c.1052G>C p.R351T | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV56333122; called by muse, mutect2, varscan2
- POLA1 | c.1983G>C p.K661N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100984979, COSV66886120; called by muse, mutect2
- POU3F2 | c.1139C>A p.S380* | Nonsense Mutation (SNP) | VAF 57/81 reads (70%) | catalogued as COSV60409389; called by muse, mutect2, varscan2
- PPIP5K1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 59/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58479977; called by muse, mutect2, varscan2
- PRAG1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs376262756; called by muse, mutect2, varscan2
- PRSS37 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV63339855; called by muse, mutect2, varscan2
- PTCD2 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100348742; called by muse, mutect2
- PTPRN2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753877997, COSV67053714; called by muse, mutect2, varscan2
- RALGAPB | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV99484678; called by muse, mutect2
- REXO1 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs768816944, COSV50085108; called by muse, mutect2, varscan2
- RNF113A | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 115/337 reads (34%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV65097674; called by muse, mutect2, varscan2
- RNF135 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs141191751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL4 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 55/277 reads (20%) | catalogued as COSV53854762; called by muse, mutect2, varscan2
- SLC5A1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.7); catalogued as rs202145392, COSV99833562; called by muse, mutect2, varscan2
- SMAD5 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV72597502; called by muse, varscan2
- SPAG9 | c.3431C>G p.S1144C (on ENST00000262013 / NM_001130528.3; = p.S1130C on NM_003971.6) | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56240488; called by muse, mutect2, varscan2
- SRCAP | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV52677946; called by muse, mutect2, varscan2
- SRD5A3 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV51712911; called by muse, mutect2, varscan2
- SRRT | c.2230A>G p.K744E | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV53820133; called by muse, mutect2, varscan2
- TBX4 | c.981G>C p.Q327H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV53608882, COSV53610345; called by muse, mutect2, varscan2
- TRIM47 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV54669102, COSV54669248; called by muse, mutect2, varscan2
- TTLL12 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as COSV53356443; called by muse, varscan2
- TUBD1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 175/425 reads (41%) | catalogued as COSV57873884, COSV57874703; called by muse, mutect2, varscan2
- UBFD1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs756180251, COSV54842760; called by muse, mutect2, varscan2
- UGT2B15 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs148054959; called by muse, mutect2, varscan2
- USF3 | c.4497G>C p.E1499D | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100324691; called by muse, mutect2
- VPS13D | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 111/208 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV62532734; called by muse, mutect2, varscan2
- WASHC2C | c.2039G>C p.S680T | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100313775; called by muse, mutect2, varscan2
- WASHC4 | c.2312T>A p.L771H | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59891213; called by muse, mutect2, varscan2
- WDR49 | c.455C>T p.T152I (on ENST00000308378 / NM_001366158.1; = p.T493I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV57704545; called by muse, mutect2, varscan2
- WDR74 | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 32/55 reads (58%) | catalogued as COSV53681116; called by muse, mutect2, varscan2
- WNT5A | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224712; called by muse, mutect2
- ZBTB37 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.611); catalogued as rs1169765598, COSV62933785; called by muse, varscan2
- ZFAND5 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52989215; called by muse, mutect2, varscan2
- ZNF148 | c.2373G>C p.Q791H | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV62306564; called by muse, mutect2, varscan2
- ZNF384 | c.1714G>T p.E572* (on ENST00000361959; = p.E511* on NM_133476.5) | Nonsense Mutation (SNP) | VAF 80/327 reads (24%) | catalogued as COSV58554251, COSV58555980; called by muse, mutect2, varscan2
- ZNF433 | c.1925G>C p.G642A | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV61399940; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs140360205; called by muse, mutect2, varscan2
- ZNF607 | c.49C>G p.H17D | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62205979; called by muse, varscan2
- ZNF776 | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as COSV100414065; called by muse, mutect2
- ZNF846 | c.1078C>A p.H360N | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101194259; called by muse, mutect2
- CNGB1 | c.2690_2698del p.M897_S899del | In Frame Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- DSP | c.4129_4130insGA p.I1377Rfs*20 | Frame Shift Ins (INS) | VAF 69/115 reads (60%) | called by mutect2, pindel, varscan2
- FAM186B | c.1637delinsAA p.R546Kfs*54 | Frame Shift Ins (INS) | VAF 14/143 reads (10%) | called by mutect2*, pindel
- KPNA6 | c.54del p.N19Tfs*4 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by pindel, varscan2
- RBCK1 | c.1515C>G p.S505R (on ENST00000356286 / NM_031229.4; = p.S463R on NM_006462.6) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.022); called by muse, mutect2
- TADA2A | c.574T>G p.F192V | Missense Mutation (SNP) | VAF 230/494 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ANKRD27 | c.2397G>A p.S799= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs752094955, COSV60129263; called by muse, mutect2, varscan2
- ANXA6 | c.1503C>T p.L501= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1428099180, COSV62907672; called by muse, varscan2
- ATAD2 | c.2163G>A p.Q721= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as COSV54884760; called by muse, mutect2, varscan2
- C16orf70 | c.1089G>A p.E363= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV54628600; called by muse, mutect2, varscan2
- C17orf49 | c.225G>A p.Q75= | Silent (SNP) | VAF 132/258 reads (51%) | catalogued as rs756124967, COSV66080946; called by muse, mutect2, varscan2
- CCDC50 | c.42C>G p.V14= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100484180, COSV61280348; called by muse, mutect2
- CHD1L | c.651C>T p.L217= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs141884816; called by muse, varscan2
- CLEC11A | c.810C>T p.P270= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV51574655; called by muse, mutect2, varscan2
- COPA | c.2889C>T p.Y963= | Silent (SNP) | VAF 36/164 reads (22%) | catalogued as rs201477148, COSV99614526; called by muse, varscan2
- CTNND1 | c.1230C>T p.I410= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs1359126650, COSV62385179; called by muse, mutect2, varscan2
- CYP4F11 | c.15C>T p.S5= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs757697644, COSV56128644; called by muse, mutect2, varscan2
- DNAH2 | c.6588C>T p.I2196= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs754746688, COSV66717133; called by muse, mutect2, varscan2
- DOCK4 | c.5724G>A p.R1908= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs767881909, COSV101447768; called by muse, mutect2, varscan2
- EIF2AK2 | c.1005G>A p.E335= | Silent (SNP) | VAF 12/218 reads (6%) | catalogued as COSV99240258; called by muse, mutect2
- EIF2B3 | c.621G>A p.L207= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV64518160; called by muse, mutect2, varscan2
- GRIPAP1 | c.1269G>A p.R423= | Silent (SNP) | VAF 46/421 reads (11%) | catalogued as COSV64552911; called by muse, mutect2, varscan2
- JAK1 | c.2712G>A p.Q904= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV61094674; called by muse, varscan2
- LRPPRC | c.3855G>A p.P1285= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs571550652, COSV53235109; called by muse, mutect2, varscan2
- MAPK8IP3 | c.624G>A p.L208= | Silent (SNP) | VAF 33/48 reads (69%) | catalogued as COSV51724473; called by muse, mutect2, varscan2
- NUTF2 | c.204C>T p.I68= | Silent (SNP) | VAF 59/338 reads (17%) | catalogued as COSV54646946; called by muse, mutect2, varscan2
- OPA1 | c.2556G>A p.K852= (on ENST00000361510 / NM_130837.3; = p.K797= on NM_015560.3) | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV62482384; called by muse, varscan2
- PHC1 | c.1263C>G p.L421= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV101418502; called by mutect2, varscan2
- PLAT | c.507C>T p.I169= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs749630142, COSV99534949; called by muse, mutect2, varscan2
- PLXND1 | c.4410C>T p.L1470= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100138989; called by muse, mutect2, varscan2
- PRKG2 | c.894C>T p.I298= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV52329230; called by muse, mutect2, varscan2
- PRRX1 | c.681G>C p.L227= | Silent (SNP) | VAF 115/263 reads (44%) | catalogued as rs760448348, COSV53417081, COSV53417862; called by muse, mutect2, varscan2
- RCC1 | c.561G>A p.L187= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV65779871; called by muse, mutect2, varscan2
- ROCK1 | c.2556C>T p.F852= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV67697877; called by muse, mutect2, varscan2
- S1PR1 | c.60C>T p.V20= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV59513975; called by muse, mutect2, varscan2
- SOX3 | c.333G>A p.A111= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs746711756, COSV65168483; called by muse, mutect2, varscan2
- SULT1C3 | c.876G>A p.K292= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as COSV61253490, COSV61254203; called by muse, mutect2, varscan2
- TIAM1 | c.1686C>G p.L562= | Silent (SNP) | VAF 64/204 reads (31%) | catalogued as COSV54565457, COSV99739080; called by muse, mutect2, varscan2
- TLN2 | c.153C>T p.L51= | Silent (SNP) | VAF 57/232 reads (25%) | catalogued as COSV60893136; called by muse, varscan2
- TOM1L2 | c.825C>T p.L275= (on ENST00000379504 / NM_001350333.2; = p.L225= on NM_001033551.3) | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV58888003; called by muse, mutect2, varscan2
- TSHZ3 | c.408C>T p.L136= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV53678207; called by muse, mutect2, varscan2
- XPNPEP1 | c.369C>G p.L123= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs149560401; called by muse, mutect2
- ZBTB37 | c.825G>T p.V275= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV62933802; called by muse, varscan2
- ZMPSTE24 | c.207C>G p.L69= | Silent (SNP) | VAF 49/215 reads (23%) | catalogued as CD105203, COSV65639937; called by muse, mutect2, varscan2
- ZNF155 | c.1179C>T p.V393= | Silent (SNP) | VAF 82/161 reads (51%) | catalogued as rs182923802; called by muse, mutect2, varscan2
- ZNF227 | c.1551G>A p.E517= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV57313217; called by muse, mutect2, varscan2
- AQR | c.471+1074C>G | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- GPR132 | c.-2G>T | 5'UTR (SNP) | VAF 46/246 reads (19%) | catalogued as COSV100317402; called by muse, mutect2, varscan2
- NMNAT2 | c.86-10937C>T | Intron (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99679669; called by muse, mutect2
- SSPOP | n.7216C>G | RNA (SNP) | VAF 25/50 reads (50%) | catalogued as COSV50488694; called by muse, mutect2, varscan2
